Somatic mutation profile of tumor specimen ALCH-B2UM-TTP1-A (aliquot ALCH-B2UM-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2UM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.2 years (24,164 days).
Specimen ALCH-B2UM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65a9af18-ae76-4277-b61a-b9e05ec8b2dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UM-NB1-A (Blood Derived Normal), aliquot ALCH-B2UM-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68428ba4-f461-4893-84f6-c78eddefdd65

The open-access MAF lists 137 somatic variants for this specimen: 92 protein-altering or splice-affecting, 24 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 24, Nonsense Mutation 6, Intron 6, RNA 5, Splice Site 4, 5'Flank 4, 3'UTR 2, 3'Flank 2, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 27/257 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BRINP3 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV100818761; called by muse, mutect2
- C9orf50 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.749); catalogued as rs1341160991; called by muse, mutect2, varscan2
- CD163L1 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs770046756, COSV58015678; called by muse, mutect2, varscan2
- DUSP19 | c.427-1G>T p.X143_splice | Splice Site (SNP) | VAF 3/41 reads (7%) | catalogued as COSV61194119; called by muse, mutect2
- E2F8 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV51461557, COSV51465756; called by muse, mutect2
- ERC2 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1400052017, COSV55599674, COSV55650029, COSV99886777; called by muse, mutect2
- ERICH3 | c.1605A>T p.K535N | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV58613260; called by muse, mutect2, varscan2
- FBN2 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 22/439 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52493432; called by muse, mutect2
- GFPT2 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53812250; called by muse, mutect2
- KIRREL3 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs1489567467, COSV69384154; called by muse, mutect2, varscan2
- KRTAP5-1 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV66299236; called by muse, varscan2
- LRRC4C | c.957G>A p.M319I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV53420018; called by muse, mutect2
- LY6D | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV56661206; called by muse, mutect2, varscan2
- MARCHF1 | c.176C>G p.T59R (on ENST00000274056; = p.T42R on NM_017923.4) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.866); catalogued as COSV56822204; called by muse, mutect2
- MGAM | c.689G>T p.R230I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71885323; called by muse, mutect2
- MOCS1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 14/268 reads (5%) | catalogued as rs1266681695, CM111815, COSV57935999; called by muse, mutect2
- NBPF10 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 51/932 reads (5%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.96); catalogued as rs782087911; called by muse, mutect2
- NEXN | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs1484326712, COSV104396111; called by muse, mutect2, varscan2
- NLRP12 | c.1055G>C p.R352P | Missense Mutation (SNP) | VAF 16/296 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV60746443; called by muse, mutect2
- NRG1 | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1234290009, COSV99828277; called by muse, mutect2, varscan2
- NXPE4 | c.769A>T p.M257L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV64943669; called by muse, mutect2, varscan2
- OR10J5 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58387085; called by muse, mutect2
- PADI4 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV100966743; called by muse, mutect2
- PALM3 | c.529G>T p.A177S (on ENST00000340790; = p.A192S on NM_001145028.2) | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV54598550; called by muse, mutect2
- PCDHB8 | c.1591C>T p.R531W | Missense Mutation (SNP) | VAF 16/616 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as rs781850313, COSV50758133; called by muse, mutect2
- PCLO | c.3617C>T p.S1206L | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1327554957; called by muse, mutect2
- PLPPR4 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV64566838; called by muse, mutect2
- RFTN2 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54387025, COSV54387981; called by muse, mutect2, varscan2
- SCN5A | c.127C>T p.R43* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | catalogued as rs1553607597, HM080101, COSV60067119; called by muse, mutect2, varscan2
- SDCCAG8 | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV59409470; called by muse, mutect2
- SH2D4B | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.663); catalogued as rs1289147542, COSV57893258; called by muse, varscan2
- SIGLEC14 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55780471; called by muse, mutect2, varscan2
- SLC26A1 | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV68310298; called by muse, mutect2
- SLC8A3 | c.1152C>A p.S384R | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs762324070; called by muse, mutect2
- SMARCA4 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1415464964, COSV60787372; called by muse, mutect2
- SMU1 | c.644C>G p.S215* | Nonsense Mutation (SNP) | VAF 10/162 reads (6%) | catalogued as COSV68140374; called by muse, mutect2
- TMEM229A | c.1093G>T p.D365Y | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1198615936; called by muse, mutect2
- XIRP2 | c.6220A>G p.K2074E (on ENST00000628543; = p.K2249E on NM_152381.6) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV54694770; called by muse, mutect2
- ABRAXAS1 | c.635T>A p.V212E | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADH6 | c.758A>C p.E253A | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2
- AGBL2 | c.157C>G p.Q53E | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2
- ALPK2 | c.4561T>A p.L1521I | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.254); called by muse, mutect2
- ANO3 | c.1075C>A p.Q359K | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- ARHGEF10 | c.1823G>A p.R608K (on ENST00000398564; = p.R583K on NM_014629.4) | Missense Mutation (SNP) | VAF 7/203 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.065); called by muse, mutect2
- BSND | c.755A>G p.E252G | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.04); called by muse, mutect2
- CBLL1 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- CEP192 | c.1633G>T p.A545S | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.274); called by muse, mutect2
- CUL1 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DCLRE1C | c.1450G>C p.G484R (on ENST00000378278 / NM_001350965.2; = p.G369R on NM_022487.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.021); called by mutect2, varscan2
- DSG1 | c.2239T>C p.F747L | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- EEA1 | c.2606T>C p.L869S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ENAM | c.417G>C p.L139F | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.299); called by muse, mutect2
- EPHB2 | c.1091G>T p.S364I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.864); called by muse, mutect2
- FLG | c.3297C>A p.H1099Q | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2
- FRG2C | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- GLYATL2 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPATCH8 | c.46-1G>T p.X16_splice | Splice Site (SNP) | VAF 25/213 reads (12%) | called by muse, mutect2, varscan2
- GPATCH8 | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 20/279 reads (7%) | called by muse, mutect2
- GRIN2B | c.4120A>T p.S1374C | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP2 | c.1687G>T p.G563C (on ENST00000619221; = p.G466C on NM_001080423.4) | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GSC | c.661T>G p.S221A | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2
- HFM1 | c.2810T>A p.I937N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HLA-G | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.04); called by muse, mutect2
- IGKV2D-29 | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- LGI1 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 12/307 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2
- LILRB2 | c.572G>T p.R191M | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2
- LRRFIP2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 27/310 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRIQ3 | c.1822G>T p.A608S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- MAGI2 | c.1741A>C p.T581P | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MANBA | c.2473C>A p.H825N (on ENST00000642252; = p.H779N on NM_005908.4) | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- MIER1 | c.1171G>A p.E391K (on ENST00000355356 / NM_001077701.3; = p.E408K on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- MRPS5 | c.184A>T p.S62C | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- MYCBP2 | c.369G>A p.W123* (on ENST00000357337; = p.W161* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 21/269 reads (8%) | called by muse, mutect2
- PADI4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0.001); called by muse, mutect2
- PDIA5 | c.170-2A>G p.X57_splice | Splice Site (SNP) | VAF 10/179 reads (6%) | called by muse, mutect2
- POM121L2 | c.2936C>A p.A979D | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); called by muse, mutect2
- PRMT8 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO2 | c.3248C>T p.P1083L | Missense Mutation (SNP) | VAF 15/164 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- SACS | c.457+1G>C p.X153_splice | Splice Site (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- SEC14L5 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2
- SERAC1 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINA12 | c.723G>A p.M241I | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SI | c.3646C>A p.P1216T | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- SIGLEC6 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- TRGV10 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2
- TRIM6-TRIM34 | c.1409G>T p.C470F | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2
- USP17L3 | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 46/259 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- VIT | c.991C>G p.L331V (on ENST00000389975 / NM_001177969.1; = p.L346V on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- VPS13A | c.2928G>C p.L976F | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- WDR17 | c.1876A>C p.I626L | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZNF250 | c.831_834del p.H277Qfs*73 | Frame Shift Del (DEL) | VAF 26/203 reads (13%) | called by pindel, varscan2
- ATAD3C | c.399C>T p.L133= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as rs1248626475, COSV101112638; called by muse, mutect2
- BOC | c.2733C>A p.L911= | Silent (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- CA12 | c.543G>A p.P181= | Silent (SNP) | VAF 28/439 reads (6%) | catalogued as rs371863633; called by muse, mutect2
- CUL1 | c.345A>T p.V115= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs1285407422; called by muse, mutect2
- CYTL1 | c.390C>A p.V130= | Silent (SNP) | VAF 43/334 reads (13%) | called by muse, mutect2, varscan2
- DYM | c.519A>G p.V173= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- EHD3 | c.1047A>G p.S349= | Silent (SNP) | VAF 12/114 reads (11%) | catalogued as COSV59032689; called by mutect2, varscan2
- GIPR | c.981A>G p.T327= | Silent (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- HHATL | c.645C>T p.P215= | Silent (SNP) | VAF 26/310 reads (8%) | catalogued as rs755729658; called by muse, mutect2
- ITIH2 | c.2478T>G p.V826= | Silent (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- LRRC4C | c.267G>A p.Q89= | Silent (SNP) | VAF 12/241 reads (5%) | called by muse, mutect2
- MARK1 | c.114G>A p.Q38= | Silent (SNP) | VAF 34/420 reads (8%) | called by muse, mutect2
- NTNG1 | c.183G>A p.L61= | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV53974648; called by muse, mutect2, varscan2
- OR1I1 | c.435G>T p.L145= | Silent (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- OR4A47 | c.807G>A p.V269= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- PCDH17 | c.945G>C p.G315= | Silent (SNP) | VAF 23/181 reads (13%) | called by muse, mutect2, varscan2
- PIGO | c.2511C>T p.V837= | Silent (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- PLXNA4 | c.234G>A p.L78= | Silent (SNP) | VAF 19/342 reads (6%) | called by muse, mutect2
- PPP1R3A | c.1723C>A p.R575= | Silent (SNP) | VAF 15/161 reads (9%) | catalogued as COSV52881791; called by muse, mutect2
- PTGFRN | c.1587G>A p.V529= | Silent (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- SPTB | c.2418C>A p.A806= | Silent (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- SPTBN2 | c.4212C>T p.A1404= | Silent (SNP) | VAF 23/242 reads (10%) | called by muse, mutect2
- SYNE1 | c.20121G>T p.V6707= (on ENST00000367255 / NM_182961.4; = p.V6636= on NM_033071.3) | Silent (SNP) | VAF 21/407 reads (5%) | called by muse, mutect2
- VIPR1 | c.903C>T p.I301= | Silent (SNP) | VAF 10/220 reads (5%) | called by muse, mutect2
- AC006288.1 | n.286G>A | RNA (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- AEBP2 | c.1508+38G>T | Intron (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823757 T>A | 5'Flank (SNP) | VAF 13/209 reads (6%) | called by muse, mutect2
- ASS1 | c.*12A>G | 3'UTR (SNP) | VAF 31/460 reads (7%) | catalogued as rs781440434, COSV61688622; called by muse, mutect2
- CD3E | c.-45C>A | 5'UTR (SNP) | VAF 38/390 reads (10%) | called by muse, mutect2
- CLEC19A | chr16:19307677 G>T | 3'Flank (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- CYP21A2 | c.738+46A>T | Intron (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- FAM205BP | n.2082G>A | RNA (SNP) | VAF 16/354 reads (5%) | catalogued as rs1216396665; called by muse, mutect2
- FAM86C2P | n.127G>T | RNA (SNP) | VAF 24/324 reads (7%) | called by muse, mutect2
- GAMT | c.570+95G>T | Intron (SNP) | VAF 6/66 reads (9%) | catalogued as rs1488917800; called by muse, mutect2
- GRAMD1B | c.2127+119T>G | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- GUCD1 | c.-9G>T | 5'UTR (SNP) | VAF 4/20 reads (20%) | catalogued as rs1195528657; called by muse, mutect2, varscan2
- GUSBP10 | n.209G>T | RNA (SNP) | VAF 8/70 reads (11%) | catalogued as rs1261803105; called by muse, mutect2
- IFRD2 | chr3:50292828 C>T | 5'Flank (SNP) | VAF 12/128 reads (9%) | catalogued as rs782530996, COSV100269255; called by muse, mutect2
- KIF13A | c.146+35628G>T | Intron (SNP) | VAF 7/118 reads (6%) | called by muse, mutect2
- LSM5 | c.*59A>T | 3'UTR (SNP) | VAF 19/132 reads (14%) | catalogued as rs1415507594, COSV99776384; called by muse, mutect2, varscan2
- PHACTR1 | c.251-119676C>G | Intron (SNP) | VAF 10/147 reads (7%) | catalogued as COSV100275545; called by muse, mutect2
- PTENP1 | n.1492T>C | RNA (SNP) | VAF 10/139 reads (7%) | catalogued as rs900212378; called by muse, mutect2
- RBP4 | chr10:93601730 C>T | 5'Flank (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- SLC35A2 | chrX:48911901 C>A | 5'Flank (SNP) | VAF 11/234 reads (5%) | catalogued as rs1557044230; called by muse, mutect2
- TTC12 | chr11:113368425 G>C | 3'Flank (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2
